Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5J9, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5J9-01A (Primary Tumor).

[page 1 of 2]
Patient Name:

Sex: Female

ICD-O-3

Carcinoma, adrenal cortical 8370/3

Site Ⓡ Adrenal Gland, cortex C74.0

Spec 1/30/13

Macroscopy

One vessel containing a material immersed in formaldehyde solution, described as following: product of resection of right adrenal mass, weighting 316 g and measuring 11 x 9 x 6.5 cm. The mass is involved by a thick brown capsule. The cut surface is characterized by a multinodular appearance, with some areas of a light brown color and some areas of hemorrhage friable consistency. The remaining adrenal parenchyma is evident and measures 1.5 x 1.0 cm. The surgical margins were stained with green indian ink.

Conclusion:

Product of right adrenalectomy and right adrenal mass resection: Adrenocortical carcinoma with the following features:

- Largest diameter – 11 cm.
- Nuclear grade (Fuhrman) – 3
- Diffuse architectural pattern – present
- Clear cells in < 25% of the neoplasm – present
- Areas on necrosis – present
- Mitotic count – 6 in 50 H.P.F.
- Atypical mitosis – absent
- Capsular invasion – not detected
- Venous invasion – not detected
- Sinusoidal invasion – present

Source: NCI Genomic Data Commons file b979c03c-9539-4791-b08f-7262255b9892 (TCGA-OR-A5J9.4C775CF4-39D7-4246-87A4-4659783A1C18.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).